Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A1KX, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A1KX-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Gastric & Mixed Tumo
Account #: [REDACTED] Date of Procedure:
DOB: [REDACTED] Date of Receipt:
Physician: [REDACTED]
CC: [REDACTED]

ICD-0-3

dedifferentiated liposarcoma, 8858/3

Site: retroperitoneum C48.0

2/21/11
mu

Specimens Submitted:

- 1: SP: Radical resection of pelvic liposarcoma, resection of rectosigmoid
2: SP: Scar abdomen

DIAGNOSIS:

1. SOFT TISSUE AND BOWEL SEGMENT, PELVIS; RESECTION:

- DEDIFFERENTIATED LIPOSARCOMA.
- THE DEDIFFERENTIATED COMPONENT PREDOMINATES, WITH MYXOFIBROSARCOMA-LIKE GROWTH, RANGING FROM LOW TO HIGH GRADE AREAS.
- A MINOR COMPONENT OF WELL-DIFFERENTIATED LIPOSARCOMA, SCLEROSING TYPE, IS PRESENT.
- TUMOR SIZE: 12.6 X 11.4 X 6.5 CM.
- THE TUMOR IS PREDOMINANTLY VIABLE WITH FOCAL AREAS OF NECROSIS.
- RESECTION MARGINS ARE FREE (TUMOR SURROUNDED GROSSLY BY AN INTACT MEMBRANE).
- TUMOR INVOLVES SUBSEROSAL FAT.
- BOWEL MARGINS ARE UNINVOLVED.
- UNREMARKABLE SEGMENT OF COLON.

2. SKIN, SCAR, ABDOMINAL WALL; EXCISION:

- SKIN WITH SCAR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1.) The specimen is received fresh labeled, "radical resection of pelvic liposarcoma, resection of rectosigmoid", and consists of one irregular,

** Continued on next page **

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: [REDACTED]

Date of Report: [REDACTED]

----- Page 2 of 3

round fragment of soft tissue (14.8 X 12.5 x 7.8 cm), with attached segment of bowel measuring 23.5 cm in length and 2.5 cm in diameter. The surface of the specimen is predominantly smooth, yellow/pink, covered by an intact translucent membrane. The bowel segment is stretched by the bulging mass which appears to arise outside of the bowel, pushing the bowel wall. Serosal surface of the specimen is inked black, and irregular surface is inked blue. The cut section reveals white/ tan to yellow, multilobulated soft mass (12.6 x 11.4 x 6.5 cm) with gelatinous areas, and foci of dark red, hemorrhagic appearance. The mass abuts the serosal , as well as irregular resection surface. The tumor pushes into, but grossly does not appear to invade the bowel wall. The bowel reveals intact, smooth tan and velvety mucosa. The specimen is photographed, portion of the tumor is submitted for

Summary of sections:

BMA -- bowel resection margin (stapled end)

BMB -- bowel resection margin (open end)

BU -- unaffected bowel

BT -- bowel with underlying tumor

IRM -- irregular surface margin

SS -- serosal surface

RST -- representative sections tumor

2).The specimen is received in formalin, labeled, " Scar abdomen ", and consists of a strip of wrinkled white tan skin measuring 10.5 x 1.1 x 0 .8cm. The surface of the skin shows a scarred appearance. A representative section is submitted.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: SP: Radical resection of pelvic liposarcoma, resection of rectosigmoid

Block	Sect.	Site	PCs
1		BMA	1
1		BMB	1
2		BT	2
1		BU	1
5		IRM	5
7		RST	7
5		SS	5

Part 2: SP: Scar abdomen

Block	Sect.	Site	PCs
1		U	1

**** Continued on next page ****

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service:

Page 3 of 3

** End of Report **

Source: NCI Genomic Data Commons file ee5fa3e3-be03-4f94-9aba-c669b7afe04c (TCGA-DX-A1KX.13532A80-F1D0-4451-9B58-52736E573426.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).